Somatic mutation profile of tumor specimen 08296da7-70ea-44df-8646-09f2cc (aliquot 08296da7-70ea-44df-8646-09f2cc_D6) from CPTAC case 04OV012, project CPTAC-2 (Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IIIC.
Specimen 08296da7-70ea-44df-8646-09f2cc: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f36b3834-1d8f-4da0-b2db-c8e6a3a44397.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 9751077c-61c1-49df-9b6f-db7d6e (Blood Derived Normal), aliquot 9751077c-61c1-49df-9b6f-db7d6e_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa9243c5-fd0b-4e23-8507-310c0757b158

The open-access MAF lists 84 somatic variants for this specimen: 56 protein-altering or splice-affecting, 21 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 21, Intron 3, Frame Shift Del 3, RNA 2, 5'Flank 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 42/376 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FANCD2 | c.3922C>T p.Q1308* | Nonsense Mutation (SNP) | VAF 36/278 reads (13%) | catalogued as rs148471911; called by muse, mutect2, varscan2
- HACL1 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58255203; called by mutect2, varscan2
- KRTAP9-2 | c.368C>A p.P123H | Missense Mutation (SNP) | VAF 37/312 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1158369177; called by mutect2, varscan2
- MCM4 | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 37/255 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs774767030; called by muse, mutect2, varscan2
- OR6A2 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs530920589, COSV60265102; called by muse, mutect2, varscan2
- OR8A1 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 41/312 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.133); catalogued as rs751076359, COSV52509364; called by muse, mutect2, varscan2
- PLXDC2 | c.332C>G p.T111R | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV65906496; called by muse, mutect2, varscan2
- SERINC3 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.341); catalogued as rs143381118; called by muse, mutect2, varscan2
- SH3YL1 | c.730T>C p.S244P | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1328241304; called by muse, mutect2, varscan2
- VOPP1 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53386082, COSV53386283; called by muse, mutect2
- ZNF404 | c.81G>C p.Q27H | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60987979; called by muse, mutect2
- ABCC2 | c.1043C>A p.S348Y | Missense Mutation (SNP) | VAF 66/506 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, varscan2
- ADAMTS19 | c.1077_1078del p.L360Kfs*5 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel
- AIFM1 | c.1114G>C p.V372L | Missense Mutation (SNP) | VAF 29/374 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.398); called by muse, mutect2
- AKIP1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- APAF1 | c.1294T>G p.S432A (on ENST00000551964 / NM_181861.2; = p.S421A on NM_001160.3) | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ARHGEF9 | c.739T>G p.C247G | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ART3 | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.065); called by muse, mutect2
- C4orf50 | c.456A>T p.R152S (on ENST00000324058; = p.R1384S on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- CACNA1G | c.2639G>C p.S880T | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CAMK1 | c.835G>C p.D279H | Missense Mutation (SNP) | VAF 20/337 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2
- CASP10 | c.179A>G p.D60G | Missense Mutation (SNP) | VAF 27/446 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- CDH3 | c.2040G>T p.K680N | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); called by muse, mutect2
- CKAP5 | c.5432A>C p.K1811T (on ENST00000529230 / NM_001008938.4; = p.K1751T on NM_014756.3) | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.15); called by muse, mutect2
- CNNM4 | c.1111A>C p.K371Q | Missense Mutation (SNP) | VAF 28/530 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- GMCL2 | c.1496del p.P499Lfs*37 | Frame Shift Del (DEL) | VAF 34/261 reads (13%) | called by mutect2, pindel, varscan2
- GPRIN1 | c.146A>G p.Q49R | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- HEPH | c.866G>C p.R289P (on ENST00000343002; = p.R22P on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/269 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- HNRNPLL | c.602T>G p.F201C | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KLF4 | c.34G>A p.V12I | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2
- KLHL22 | c.1589T>G p.L530R | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAF1 | c.198_212+1del | Frame Shift Del (DEL) | VAF 28/270 reads (10%) | called by mutect2, pindel
- MAP7D1 | c.255G>C p.E85D | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.952); called by muse, mutect2
- MARCO | c.387C>A p.H129Q | Missense Mutation (SNP) | VAF 33/350 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2
- MCF2 | c.2306T>C p.V769A | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- NEB | c.10601A>G p.H3534R | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.438); called by muse, mutect2
- OR11H6 | c.935A>G p.N312S | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- OR4K5 | c.539A>G p.D180G | Missense Mutation (SNP) | VAF 29/533 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- OR51A2 | c.284C>A p.S95Y | Missense Mutation (SNP) | VAF 42/468 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2
- PCDH15 | c.2341G>T p.V781F | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.673); called by muse, mutect2
- PLCE1 | c.4461C>A p.N1487K | Missense Mutation (SNP) | VAF 38/505 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PXDNL | c.3494T>A p.V1165D | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- RBP3 | c.2167C>G p.P723A | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- RFX6 | c.744A>T p.Q248H | Missense Mutation (SNP) | VAF 17/330 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.277); called by muse, mutect2
- RIMBP3 | c.3056G>C p.R1019P | Missense Mutation (SNP) | VAF 66/1077 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.68); called by muse, mutect2
- SEMA3D | c.1488G>C p.E496D | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- SIX4 | c.691A>C p.K231Q | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by mutect2, varscan2
- SLCO2B1 | c.1210A>G p.I404V | Missense Mutation (SNP) | VAF 24/414 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2
- SSH1 | c.793A>G p.S265G | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); called by muse, mutect2
- TCTN2 | c.1140T>A p.N380K | Missense Mutation (SNP) | VAF 21/271 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.207); called by muse, mutect2
- TP53BP1 | c.3813+2T>G p.X1271_splice | Splice Site (SNP) | VAF 4/88 reads (5%) | called by muse, mutect2
- TPD52L3 | c.100A>G p.T34A | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- VSNL1 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 17/246 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.115); called by muse, mutect2
- WRAP73 | c.868T>C p.S290P | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- ZNF10 | c.1533T>G p.H511Q | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); called by mutect2, varscan2
- AC011462.1 | c.399G>A p.K133= | Silent (SNP) | VAF 52/427 reads (12%) | called by muse, mutect2, varscan2
- ARMCX2 | c.693A>G p.A231= | Silent (SNP) | VAF 21/360 reads (6%) | catalogued as rs782144997; called by muse, mutect2
- BCL2L14 | c.261C>G p.G87= | Silent (SNP) | VAF 28/594 reads (5%) | called by muse, mutect2
- CCN4 | c.831C>T p.Y277= | Silent (SNP) | VAF 17/144 reads (12%) | catalogued as COSV51529890; called by mutect2, varscan2
- CELF6 | c.1419G>T p.R473= | Silent (SNP) | VAF 22/102 reads (22%) | called by muse, mutect2, varscan2
- COL24A1 | c.1638T>A p.P546= | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- DCAF6 | c.1065A>G p.E355= | Silent (SNP) | VAF 7/180 reads (4%) | called by muse, mutect2
- FAM205A | c.2604G>A p.T868= | Silent (SNP) | VAF 54/478 reads (11%) | catalogued as rs778286200; called by muse, mutect2, varscan2
- GDF7 | c.813C>G p.S271= | Silent (SNP) | VAF 18/160 reads (11%) | catalogued as rs1003838424; called by muse, mutect2
- IQCH | c.2499A>G p.E833= | Silent (SNP) | VAF 26/292 reads (9%) | called by muse, mutect2
- ITPRIPL2 | c.1231C>T p.L411= | Silent (SNP) | VAF 23/266 reads (9%) | called by muse, mutect2
- MTSS2 | c.588C>T p.R196= | Silent (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- NDFIP2 | c.213G>A p.T71= | Silent (SNP) | VAF 41/176 reads (23%) | catalogued as rs1054489214; called by muse, mutect2, varscan2
- PNLIPRP1 | c.99C>T p.P33= | Silent (SNP) | VAF 13/174 reads (7%) | called by muse, mutect2
- SLC39A4 | c.897C>G p.A299= (on ENST00000301305 / NM_001374839.1; = p.A274= on NM_017767.3) | Silent (SNP) | VAF 59/581 reads (10%) | catalogued as COSV52777736, COSV52778040; called by muse, mutect2, varscan2
- STRN4 | c.627C>A p.L209= | Silent (SNP) | VAF 40/330 reads (12%) | called by muse, mutect2
- TMC4 | c.717C>G p.L239= (on ENST00000617472 / NM_001145303.3; = p.L233= on NM_144686.4) | Silent (SNP) | VAF 14/169 reads (8%) | catalogued as rs550033169; called by muse, mutect2
- TSPAN18 | c.606A>C p.L202= | Silent (SNP) | VAF 20/179 reads (11%) | called by muse, mutect2, varscan2
- TUBGCP6 | c.4350G>C p.V1450= | Silent (SNP) | VAF 10/193 reads (5%) | called by muse, mutect2
- XIRP2 | c.7962T>A p.G2654= (on ENST00000628543; = p.G2829= on NM_152381.6) | Silent (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- ZNF622 | c.123A>T p.P41= | Silent (SNP) | VAF 18/262 reads (7%) | called by muse, mutect2
- CABP1 | c.655-3922G>A | Intron (SNP) | VAF 27/388 reads (7%) | catalogued as rs552282303; called by muse, mutect2
- MIR9-1HG | n.58G>C | RNA (SNP) | VAF 29/145 reads (20%) | called by muse, mutect2, varscan2
- MUC19 | n.5967C>G | RNA (SNP) | VAF 11/188 reads (6%) | called by muse, mutect2
- MUC4 | c.15509-10C>T | Intron (SNP) | VAF 73/225 reads (32%) | catalogued as rs1323090238; called by muse, mutect2, varscan2
- PUSL1 | c.78-73C>T | Intron (SNP) | VAF 14/75 reads (19%) | called by muse, mutect2, varscan2
- RNU6-389P | chr7:55685203 T>C | 5'Flank (SNP) | VAF 28/204 reads (14%) | called by muse, mutect2, varscan2
- TLCD2 | chr17:1713779 T>A | 5'Flank (SNP) | VAF 25/179 reads (14%) | called by muse, mutect2, varscan2
